Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K2, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K2-01A (Primary Tumor).

Papillary Renal Cell Carcinoma, Type II

Stage: pT1b, R0

Grade: GIII

Laterality = (R)

ICD-O-3

Carcinoma, papillary renal cell
8260/3
Site: (R) Kidney NOS
C64.9

W6/13/14

Reviewer Initials	W5/6/14	

Source: NCI Genomic Data Commons file 49fabaf8-47fa-4915-aaad-d6b216488964 (TCGA-5P-A9K2.C8915232-ED02-4AE9-9BB0-283EAD2610AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).